Somatic mutation profile of tumor specimen C3N-01077-03 (aliquot CPT0210780006) from CPTAC case C3N-01077, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; Tumor grade: G3.
Specimen C3N-01077-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5df48ef9-87a8-40e7-8934-ae1b6f854349.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01077-71 (Blood Derived Normal), aliquot CPT0210880002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b1b4010d-03db-4d70-a20e-5de77dc36492

The open-access MAF lists 122 somatic variants for this specimen: 82 protein-altering or splice-affecting, 19 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 19, Frame Shift Del 11, Intron 10, Frame Shift Ins 5, 5'UTR 3, Splice Site 3, Nonsense Mutation 3, RNA 3, 3'UTR 3, 3'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.267del p.S90Pfs*33 | Frame Shift Del (DEL) | VAF 40/175 reads (23%) | catalogued as rs587783062; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- ABCE1 | c.1606G>C p.D536H | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV56848779, COSV99668472; called by muse, mutect2
- ACSM3 | c.1540C>T p.P514S | Missense Mutation (SNP) | VAF 32/255 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.073); catalogued as rs775920299; called by muse, mutect2, varscan2
- ADAM12 | c.2557C>A p.P853T | Missense Mutation (SNP) | VAF 17/190 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs1248558182, COSV64138190; called by muse, mutect2
- ARHGEF28 | c.2165G>A p.R722K | Missense Mutation (SNP) | VAF 8/210 reads (4%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV99708867; called by muse, mutect2
- CD2BP2 | c.12G>C p.R4S | Missense Mutation (SNP) | VAF 10/215 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59769627; called by muse, mutect2
- COL20A1 | c.3026C>T p.T1009M | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs200056990, COSV100491036; called by muse, mutect2, varscan2
- DHX35 | c.643-2A>T p.X215_splice | Splice Site (SNP) | VAF 18/51 reads (35%) | catalogued as rs765403602; called by muse, varscan2
- DNAH3 | c.7711G>A p.D2571N | Missense Mutation (SNP) | VAF 53/168 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs748250294; called by muse, mutect2, varscan2
- DOCK3 | c.5291G>T p.R1764L | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs375984390, COSV56539322; called by muse, mutect2
- EEF1AKMT3 | c.295G>T p.D99Y | Missense Mutation (SNP) | VAF 57/376 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.161); catalogued as rs1431926859, COSV100103620; called by muse, mutect2, varscan2
- FASN | c.7349C>T p.T2450M | Missense Mutation (SNP) | VAF 68/678 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.179); catalogued as rs776351410, COSV60753297; ClinVar: uncertain significance; called by muse, mutect2
- FRYL | c.14C>G p.T5R | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.298); catalogued as COSV99976025; called by muse, mutect2, varscan2
- LRRC37A2 | c.151T>G p.S51A | Missense Mutation (SNP) | VAF 87/528 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.332); catalogued as rs566862200; called by muse, mutect2, varscan2
- MAP10 | c.190A>T p.I64F | Missense Mutation (SNP) | VAF 21/140 reads (15%) | PolyPhen possibly damaging (0.696); catalogued as COSV69363498; called by muse, mutect2, varscan2
- MDN1 | c.12725C>G p.S4242C | Missense Mutation (SNP) | VAF 30/198 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.628); catalogued as COSV101020749; called by muse, mutect2, varscan2
- MKKS | c.1045G>C p.D349H | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs1291657403, COSV61397922; called by muse, mutect2, varscan2
- MROH2B | c.3014T>C p.I1005T | Missense Mutation (SNP) | VAF 62/154 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as rs923155494; called by muse, mutect2, varscan2
- NME8 | c.1333C>T p.Q445* | Nonsense Mutation (SNP) | VAF 26/158 reads (16%) | catalogued as rs768540000, COSV52249866; called by muse, mutect2, varscan2
- ORC4 | c.1128dup p.E377* | Frame Shift Ins (INS) | VAF 13/87 reads (15%) | catalogued as rs1319142824; called by mutect2, pindel, varscan2
- PLCE1 | c.647G>T p.C216F | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.768); catalogued as rs752701924; called by muse, mutect2, varscan2
- USF2 | c.20G>A p.G7D | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.081); catalogued as rs1173022597; called by muse, mutect2
- USH2A | c.13052C>T p.T4351I | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs79180293; called by muse, mutect2
- YIF1A | c.655G>A p.V219M | Missense Mutation (SNP) | VAF 65/325 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.411); catalogued as rs148907509; called by muse, mutect2, varscan2
- ABCC1 | c.4053_4056dup p.I1353Hfs*46 | Frame Shift Ins (INS) | VAF 39/304 reads (13%) | called by mutect2, pindel
- ACACB | c.219G>T p.Q73H | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- ANKRD13A | c.1005C>A p.Y335* | Nonsense Mutation (SNP) | VAF 9/205 reads (4%) | called by muse, mutect2
- ARID4B | c.1211T>A p.F404Y | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- ATG14 | c.647+1G>T p.X216_splice | Splice Site (SNP) | VAF 5/25 reads (20%) | called by muse, varscan2
- CDK14 | c.494T>A p.V165E (on ENST00000380050 / NM_001287135.2; = p.V147E on NM_012395.3) | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.992); called by muse, mutect2
- CEP97 | c.2207C>T p.S736F | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- CFHR3 | c.147del p.K49Nfs*103 | Frame Shift Del (DEL) | VAF 16/67 reads (24%) | called by pindel, varscan2
- CKAP2 | c.1306G>A p.E436K (on ENST00000378037 / NM_001098525.2; = p.E435K on NM_018204.5) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CNST | c.143A>C p.H48P | Missense Mutation (SNP) | VAF 27/232 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAAF1 | c.1319G>A p.G440E | Missense Mutation (SNP) | VAF 18/298 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); called by muse, mutect2
- DNM1L | c.1148del p.P383Hfs*11 | Frame Shift Del (DEL) | VAF 24/138 reads (17%) | called by mutect2, pindel, varscan2
- DPP10 | c.950+1G>A p.X317_splice | Splice Site (SNP) | VAF 8/94 reads (9%) | called by muse, varscan2
- EXD1 | c.650A>T p.K217I | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- FAM83B | c.1358C>G p.T453R | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.188); called by muse, mutect2
- FAT3 | c.11444C>G p.A3815G | Missense Mutation (SNP) | VAF 30/374 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.124); called by muse, mutect2
- FIP1L1 | c.1059del p.F353Lfs*35 | Frame Shift Del (DEL) | VAF 10/69 reads (14%) | called by mutect2, pindel, varscan2
- FKRP | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- GALNT5 | c.2098A>T p.M700L | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- GHITM | c.93del p.I32Sfs*8 | Frame Shift Del (DEL) | VAF 30/199 reads (15%) | called by mutect2, pindel, varscan2
- GK5 | c.1010G>C p.G337A | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GRN | c.70C>T p.Q24* | Nonsense Mutation (SNP) | VAF 64/431 reads (15%) | called by muse, mutect2, varscan2
- HERPUD1 | c.105_112del p.H36Gfs*65 | Frame Shift Del (DEL) | VAF 30/195 reads (15%) | called by mutect2, pindel
- HM13 | c.89A>T p.E30V | Missense Mutation (SNP) | VAF 81/556 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- LAMB1 | c.2615_2621del p.H872Lfs*6 | Frame Shift Del (DEL) | VAF 41/297 reads (14%) | called by mutect2, pindel, varscan2
- LAT | c.644-3C>G | Splice Region (SNP) | VAF 19/210 reads (9%) | called by muse, mutect2
- MAP1A | c.3783dup p.T1262Hfs*21 | Frame Shift Ins (INS) | VAF 47/242 reads (19%) | called by mutect2, pindel, varscan2
- MAP4K4 | c.3061G>C p.E1021Q (on ENST00000347699 / NM_001242559.2; = p.E939Q on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- MAST2 | c.1848del p.F616Lfs*27 | Frame Shift Del (DEL) | VAF 46/296 reads (16%) | called by mutect2, pindel, varscan2
- MGA | c.3929A>T p.K1310M | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.73); called by muse, mutect2
- MMP8 | c.361A>T p.T121S | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- MPEG1 | c.1528C>G p.L510V | Missense Mutation (SNP) | VAF 11/251 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.292); called by muse, mutect2
- MUC16 | c.26146T>A p.S8716T | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.01); called by muse, mutect2
- MYO9B | c.1815G>T p.Q605H | Missense Mutation (SNP) | VAF 47/156 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PBRM1 | c.3047_3049del p.E1016del (on ENST00000296302 / NM_001366071.2; = p.E991del on NM_018313.5) | In Frame Del (DEL) | VAF 6/44 reads (14%) | called by pindel, varscan2
- PCDH19 | c.169del p.Q57Rfs*15 | Frame Shift Del (DEL) | VAF 20/115 reads (17%) | called by mutect2, pindel, varscan2
- PCYT1A | c.362T>G p.F121C | Missense Mutation (SNP) | VAF 36/263 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- PDE4DIP | c.5749C>A p.Q1917K | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- RANBP2 | c.1871A>G p.E624G | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RASSF8 | c.1021A>G p.T341A | Missense Mutation (SNP) | VAF 39/202 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- RAX2 | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 85/497 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- RDH10 | c.893T>A p.F298Y | Missense Mutation (SNP) | VAF 11/184 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.121); called by muse, mutect2
- RERGL | c.234T>G p.D78E | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RPL15 | c.63T>A p.F21L | Missense Mutation (SNP) | VAF 9/151 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.5); called by muse, mutect2
- RPL15 | c.64C>T p.L22F | Missense Mutation (SNP) | VAF 9/154 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.25); called by muse, mutect2
- SEMA6A | c.2948T>C p.V983A | Missense Mutation (SNP) | VAF 52/128 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- SKOR1 | c.2372C>A p.P791H | Missense Mutation (SNP) | VAF 21/250 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.227); called by muse, mutect2
- SLC16A12 | c.649C>A p.L217I | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SLC1A6 | c.1423A>C p.T475P | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SPON1 | c.2208G>C p.E736D | Missense Mutation (SNP) | VAF 41/275 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPRR2A | c.108C>G p.C36W | Missense Mutation (SNP) | VAF 11/237 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SSR4 | c.334T>G p.Y112D | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SYNPO2L | c.1741T>A p.S581T (on ENST00000394810 / NM_001114133.3; = p.S357T on NM_024875.5) | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.275); called by muse, mutect2
- TPCN2 | c.351_352insA p.W118Mfs*65 | Frame Shift Ins (INS) | VAF 43/198 reads (22%) | called by mutect2, pindel, varscan2
- VAT1 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 38/441 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.06); called by muse, mutect2
- VHL | c.356_378del p.F119Wfs*5 | Frame Shift Del (DEL) | VAF 24/186 reads (13%) | called by mutect2, pindel
- ZNF516 | c.1312del p.A438Pfs*22 | Frame Shift Del (DEL) | VAF 65/274 reads (24%) | called by mutect2, pindel, varscan2
- ZNF99 | c.787_788insAG p.G263Efs*12 | Frame Shift Ins (INS) | VAF 6/38 reads (16%) | called by mutect2, pindel, varscan2
- ABCA2 | c.292C>T p.L98= (on ENST00000614293; = p.L68= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/290 reads (8%) | called by muse, mutect2
- ADAM33 | c.90G>A p.V30= | Silent (SNP) | VAF 34/225 reads (15%) | catalogued as rs1427262095; called by muse, mutect2, varscan2
- CACNA1I | c.2736G>T p.G912= | Silent (SNP) | VAF 25/123 reads (20%) | called by muse, mutect2, varscan2
- CSMD3 | c.2532G>T p.R844= (on ENST00000297405 / NM_001363185.1; = p.R740= on NM_052900.3) | Silent (SNP) | VAF 11/54 reads (20%) | called by muse, mutect2, varscan2
- CXCR4 | c.39C>A p.T13= | Silent (SNP) | VAF 32/145 reads (22%) | catalogued as COSV54011574; called by muse, mutect2, varscan2
- DDX28 | c.840C>T p.L280= | Silent (SNP) | VAF 49/285 reads (17%) | called by muse, mutect2, varscan2
- EEF1A1 | c.177C>T p.V59= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as rs1268823666; called by muse, mutect2, varscan2
- ESCO1 | c.1848A>T p.A616= | Silent (SNP) | VAF 4/20 reads (20%) | called by mutect2, varscan2
- GSE1 | c.1110G>A p.E370= | Silent (SNP) | VAF 112/625 reads (18%) | called by muse, mutect2, varscan2
- HAL | c.1464T>C p.A488= | Silent (SNP) | VAF 114/537 reads (21%) | called by muse, mutect2, varscan2
- IQGAP2 | c.3021G>A p.V1007= | Silent (SNP) | VAF 18/270 reads (7%) | catalogued as COSV57182752; called by muse, mutect2
- KIR3DL2 | c.351C>T p.V117= | Silent (SNP) | VAF 24/292 reads (8%) | called by muse, mutect2
- KRAS | c.204G>A p.R68= | Silent (SNP) | VAF 19/112 reads (17%) | catalogued as COSV55640563, COSV55650115; called by muse, mutect2, varscan2
- KRTAP4-7 | c.21C>G p.G7= | Silent (SNP) | VAF 31/159 reads (19%) | called by muse, mutect2, varscan2
- LMX1A | c.288C>A p.G96= | Silent (SNP) | VAF 26/171 reads (15%) | called by muse, mutect2, varscan2
- NETO1 | c.1224A>C p.A408= | Silent (SNP) | VAF 23/94 reads (24%) | called by muse, mutect2, varscan2
- OR10J1 | c.708T>G p.A236= | Silent (SNP) | VAF 14/166 reads (8%) | called by muse, mutect2
- PCDH12 | c.3306C>T p.G1102= | Silent (SNP) | VAF 82/589 reads (14%) | catalogued as COSV51522550; called by muse, mutect2, varscan2
- TMEM238 | c.360C>T p.S120= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as rs937738489; called by muse, mutect2, varscan2
- ACY1 | c.852+34C>A | Intron (SNP) | VAF 35/279 reads (13%) | called by muse, mutect2, varscan2
- ALMS1P1 | chr2:73700950 A>C | 3'Flank (SNP) | VAF 51/294 reads (17%) | called by muse, mutect2, varscan2
- AURKC | c.-12C>T | 5'UTR (SNP) | VAF 86/489 reads (18%) | catalogued as rs533590946; called by muse, mutect2, varscan2
- BCL9L | c.*623T>G | 3'UTR (SNP) | VAF 40/229 reads (17%) | called by muse, mutect2, varscan2
- BLK | c.1030-98C>A | Intron (SNP) | VAF 21/164 reads (13%) | called by muse, mutect2, varscan2
- BLK | c.1030-97C>A | Intron (SNP) | VAF 21/163 reads (13%) | called by muse, mutect2, varscan2
- DPF2 | c.637+11C>T | Intron (SNP) | VAF 37/196 reads (19%) | called by muse, mutect2, varscan2
- FAM13A | c.-35G>A | 5'UTR (SNP) | VAF 24/86 reads (28%) | called by muse, mutect2, varscan2
- FLYWCH1 | c.1514-259C>G | Intron (SNP) | VAF 10/27 reads (37%) | catalogued as COSV54145041; called by muse, varscan2
- MACF1 | c.15832-11502A>T | Intron (SNP) | VAF 20/120 reads (17%) | catalogued as COSV57144343; called by muse, mutect2, varscan2
- MED13L | c.2470-10C>G | Intron (SNP) | VAF 19/238 reads (8%) | called by muse, mutect2
- PCCA | c.1900-23796C>T | Intron (SNP) | VAF 19/144 reads (13%) | called by muse, mutect2, varscan2
- PRPF3 | c.-3A>C | 5'UTR (SNP) | VAF 12/194 reads (6%) | called by muse, mutect2
- RAE1 | c.1020+152del | Intron (DEL) | VAF 73/309 reads (24%) | called by mutect2, pindel, varscan2
- RBP5 | c.*6G>C | 3'UTR (SNP) | VAF 16/167 reads (10%) | called by muse, mutect2, varscan2
- RPS4XP21 | n.41C>A | RNA (SNP) | VAF 42/197 reads (21%) | catalogued as rs1015671738; called by muse, mutect2, varscan2
- SSPOP | n.5689C>T | RNA (SNP) | VAF 24/198 reads (12%) | catalogued as rs773859304; called by muse, mutect2, varscan2
- SVIL2P | n.1677G>A | RNA (SNP) | VAF 17/144 reads (12%) | called by muse, mutect2, varscan2
- TAPT1 | chr4:16227039 C>T | 5'Flank (SNP) | VAF 34/182 reads (19%) | called by muse, varscan2
- TNNI2 | c.*17A>G | 3'UTR (SNP) | VAF 42/548 reads (8%) | called by muse, mutect2
- UBP1 | c.1585+18G>A | Intron (SNP) | VAF 3/18 reads (17%) | called by muse, varscan2
